Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8439, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8439-01A (Primary Tumor).

[page 1 of 5]
DIAGNOSIS:

1. Renal, tumor #1, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
2. Renal, tumor #4, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
3. Renal, tumor #5, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
4. Renal, tumor #2, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
5. Renal, tumor #3, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
6. Renal, tumor #6, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
7. Renal, tumor #7, left, partial nephrectomy: Renal cell carcinoma, chromophobe type.
8. Renal, tumor #8, left, partial nephrectomy: Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II / III. Renal cell Carcinoma, Chromophobe type. See note.
9. Renal, tumor #9, left, partial nephrectomy: Renal cell carcinoma, clear cell type, Fuhrman nuclear grade II / III. Renal cell carcinoma, Chromophobe type. See note.

NOTE: In specimens 8 and 9, two grossly and morphologically different tumor masses are identified; one is a clear cell RCC and the other one an RCC chromophobe type.

Patient Identification

[page 2 of 5]
[REDACTED]

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: [REDACTED] Brief Clinical History: [REDACTED] yo
male with bilateral renal tumors and no known family history of renal
cancer, attention [REDACTED]
[REDACTED]

PROCEDURE: Pre-Operative Diagnosis: renal tumors Post-Operative Diagnosis: renal
tumors Operative Findings: diffuse involvement of left kidney with
renal tumors; minimal normal parenchyma observed on intraoperative
sonogram

SPECIMENS SUBMITTED: 1. TUMOR, Left kidney # 1 (1FS)
2. TUMOR, Left kidney # 4 (2FS)
3. TUMOR, Left kidney # 5 (3FS)
4. TUMOR, Left kidney # 2
5. TUMOR, Left kidney # 3
6. TUMOR, Left kidney # 6
7. TUMOR, Left kidney # 7
8. TUMOR, Left kidney # 8
9. TUMOR, Left kidney # 9

INTRAOPERATIVE CONSULTATION:

1. "Tumor #1 left kidney"
1FS diagnosis: Oncocytic neoplasm, favoring oncocytoma.
2. "Tumor #4 left kidney"
2FS diagnosis: Oncocytic neoplasm.
3. "Tumor #5 left kidney"
3FS diagnosis: Oncocytic neoplasm.

These findings were reported by [REDACTED]

GROSS DESCRIPTION:

Patient Identification

[page 3 of 5]
Received fresh from the OR is a specimen labeled with the patient's name, medical record number, and further specified as:

1. "tumor #1 left kidney". It is an ovoid red to pink nodular tissue fragment measuring 2 x 1.5 x 0.8 cm. It is trisected revealing a pink-tan homogeneous cut surface. The central slice is frozen as "1FS". Received in the Gross Pathology Lab is a specimen matching the above description. The portion submitted as frozen section is transferred to an orange cassette labeled 1FS. A second of the trisected pieces is submitted in cassette labeled or permanent processing.
2. "tumor #4 left kidney". It consists of a red to tan 2.5 x 1.8 x 1 cm tissue fragment. It was trisected and the middle section is submitted as 2FS. Received in the Gross Pathology Lab is a specimen matching the above description. The section submitted for frozen is transferred to an orange cassette labeled 2FS for permanent processing. Representative further sections are taken and submitted in cassettes 2A and 2B.
3. "tumor #5 left kidney". It consists of a red-tan 5 x 5 x 3.5-cm tissue fragment. It was bisected to reveal a red to tan hemorrhagic cut surface. Representative sections are frozen as 3FS. Received in the Gross Pathology Lab is a specimen matching the above description. The frozen specimen was transferred to an orange cassette labeled 3FS for permanent processing. Cassettes 3A-3G contains representative sections of the tumor.
4. "tumor #2 left kidney". It is a dome-shaped red to pink nodular tissue fragment measuring 2 x 1.4 x 0.7 cm. It is bisected revealing a homogeneous tan to pink cut surface with central hemorrhage. Approximately 60% of the tissue is procured for UOB. Gross photographs are taken and the remainder of the specimen is placed in formalin and submitted to Pathology for permanent processing. In the Gross Pathology Lab a specimen matching the above description is received. It is entirely submitted in a cassette labeled or permanent processing.
5. "Tumor #3 left kidney". It is a dome-shaped red to pink nodular tissue fragment measuring 1.8 x 1.4 x 0.5 cm. It is bisected revealing a hemorrhagic maroon/red cut surface. Approximately 50% of the tissue is procured for UOB. Gross photographs are taken and the remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in the Gross Pathology Lab is a specimen matching the above description. A representative section is submitted in a cassette labeled or permanent processing.
6. "Tumor #6 left kidney". The specimen is a spherical pink to red nodular tissue fragment measuring 4.8 x 4.8 x 4.7 cm. It is bisected revealing a focally disrupted tan to pink nodular tissue fragment that is homogeneous. The surface is tan to pink and fleshy. Approximately 30% of the tissue is procured for UOB. Gross photographs are taken and the remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in the Gross Pathology Lab is a specimen matching the above description. Representative sections are submitted in cassettes 6A-6E. Cassette 6A

Patient Identification

[page 4 of 5]
contains a portion of adjacent tissue that has a distinct smooth creamy texture compared to the rest of the lesion.

- 7. "Tumor #7 left kidney". The specimen consists of 2 fragments that are red to tan soft tissue and 1 yellow to pink soft tissue fragment measuring from 2.5 to 4.5 cm in greatest dimension. The largest fragment is bisected revealing a variegated maroon to pink hemorrhagic cut surface measuring 4.5 x 3.5 x 3. Approximately 50% of tissue from the largest fragment is procured for UOB. Gross photographs are taken and the remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in the Gross Pathology Lab is a specimen matching the above description. Representative sections are taken and submitted in cassettes labeled 7A-7F for permanent processing.
- 8. "Tumor #8 left kidney" is a focally disrupted ovoid pink to tan nodular tissue fragment measuring 5.5 x 5 x 3.5 cm. It is bisected revealing a tan-pink fleshy cut surface with a well-circumscribed yellow to tan spherical nodule, 1.2 cm in greatest diameter, at the periphery. Approximately 50% of the tissue, spherical tan nodule, and 20% of the rest of the specimen are procured. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in the Gross Pathology Lab is a specimen matching the above description. Representative sections of the specimen are taken and submitted in cassettes 8A-8E. Please note that 8E contains a representative section of the nodule described.
- 9. "Tumor #9 left kidney". It is a binodular pink to tan tissue fragment overall measuring 2 x 1.5 x 1.5 cm. One nodule is well-circumscribed and solid homogeneous and tan measuring 1.3 cm. The other is ill-defined, hemorrhagic, and variegated maroon to tan and measuring 1.2 cm. Approximately 50% of tissue is procured for UOB. Gross photographs are taken and the remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Pathology is a specimen matching the above description. The two fragments are submitted in white cassettes labeled 9A and 9B.

[Redacted]

[Redacted]

AZR1 [Redacted]

[Redacted]

[Redacted] identification

[Redacted]

[page 5 of 5]
Patient Identification

Surgical Pathology Report
NIH-2772 (7/97)
P.A. 09-25-0099
File in Section 3: Tissue Examination

Source: NCI Genomic Data Commons file 4f5f5f64-a18d-439e-a5fa-8c770836f0d9 (TCGA-KM-8439.174672EF-6475-44C2-9934-8726B8E5E98E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).